Somatic mutation profile of tumor specimen C3L-06433-01 (aliquot CPT0335430006) from CPTAC case C3L-06433, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 68.1 years (24,877 days).
Specimen C3L-06433-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Head & Neck; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4d96229c-3bd0-4bc6-afab-b4fa8785c84c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06433-31 (Blood Derived Normal), aliquot CPT0335420002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/60872e46-3536-429d-bbf1-482beecfd343

The open-access MAF lists 1,174 somatic variants for this specimen: 763 protein-altering or splice-affecting, 362 silent, 49 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 700, Silent 362, Nonsense Mutation 39, Intron 28, Splice Region 10, Splice Site 7, RNA 5, 3'UTR 4, 5'Flank 4, 3'Flank 4, 5'UTR 4, Frame Shift Del 4.

Variants (750 of 1,174; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT3 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 99/198 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397514606, COSV55605820, COSV55624598; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARID2 | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 57/219 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1424958105, COSV57595631, COSV57607050; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 177/323 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRAF | c.1918G>A p.V640M (on ENST00000288602 / NM_001374244.1; = p.V600M on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 174/320 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs121913378, COSV56066607, COSV56075762, COSV56124012, COSV56152883; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA10 | c.2287C>T p.R763C | Missense Mutation (SNP) | VAF 62/246 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs200565917, COSV52222412; called by muse, mutect2, varscan2
- ABCA13 | c.13267C>A p.P4423T | Missense Mutation (SNP) | VAF 39/499 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as COSV68943355; called by muse, mutect2
- ABCC9 | c.2681G>A p.G894E | Missense Mutation (SNP) | VAF 58/196 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53961664; called by muse, mutect2, varscan2
- AC011005.1 | c.674C>T p.S225F | Missense Mutation (SNP) | VAF 266/613 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs1420594006; called by muse, mutect2, varscan2
- ACP3 | c.127C>T p.R43W | Missense Mutation (SNP) | VAF 65/203 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781475900, COSV60485052; called by muse, mutect2, varscan2
- ACSM2A | c.1073G>A p.R358Q (on ENST00000219054; = p.R279Q on NM_001308169.2) | Missense Mutation (SNP) | VAF 103/266 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.277); catalogued as rs188648395, COSV54581766, COSV99525176; called by muse, mutect2, varscan2
- ACVR1C | c.1321C>T p.R441* | Nonsense Mutation (SNP) | VAF 81/273 reads (30%) | catalogued as rs775081249, COSV54643616; called by muse, mutect2, varscan2
- ADAM18 | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 69/223 reads (31%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.461); catalogued as COSV55846469; called by muse, mutect2, varscan2
- ADAM2 | c.1829C>T p.S610L | Missense Mutation (SNP) | VAF 56/175 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.065); catalogued as COSV55862842; called by muse, mutect2, varscan2
- ADAM28 | c.1101G>A p.L367= | Splice Region (SNP) | VAF 61/200 reads (31%) | catalogued as COSV56098072; called by muse, varscan2
- ADAMTSL1 | c.1634G>A p.R545Q | Missense Mutation (SNP) | VAF 109/333 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs562929854, COSV52814957; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2708G>A p.R903K | Missense Mutation (SNP) | VAF 125/394 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); catalogued as COSV101001600; called by muse, mutect2, varscan2
- ADGRF4 | c.1538G>A p.R513Q | Missense Mutation (SNP) | VAF 92/413 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.381); catalogued as rs112563187, COSV51954824; called by muse, mutect2, varscan2
- ADGRL3 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 72/266 reads (27%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs1453660298, COSV72268560; called by muse, mutect2, varscan2
- ADGRL3 | c.4672C>T p.P1558S (on ENST00000506720 / NM_001322402.2; = p.P1447S on NM_015236.6) | Missense Mutation (SNP) | VAF 111/316 reads (35%) | SIFT tolerated, low confidence (0.27); PolyPhen possibly damaging (0.521); catalogued as rs1384273945; called by muse, mutect2, varscan2
- ADH4 | c.274A>T p.I92F | Missense Mutation (SNP) | VAF 72/196 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as COSV55501418; called by muse, mutect2, varscan2
- ADH7 | c.919C>T p.P307S | Missense Mutation (SNP) | VAF 112/372 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.132); catalogued as COSV52919775; called by muse, mutect2
- AGBL1 | c.2080C>T p.H694Y | Missense Mutation (SNP) | VAF 82/246 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV66847341; called by muse, mutect2, varscan2
- AKR1B15 | c.910-1G>A p.X304_splice | Splice Site (SNP) | VAF 152/446 reads (34%) | catalogued as rs770896688; called by muse, mutect2, varscan2
- AKR1C3 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 69/272 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.091); catalogued as COSV65910789; called by muse, mutect2, varscan2
- AKR1D1 | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 225/395 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM044567; called by muse, mutect2, varscan2
- ALG3 | c.892C>T p.L298F | Missense Mutation (SNP) | VAF 117/349 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.094); catalogued as rs1198482018; called by muse, mutect2, varscan2
- ALPK1 | c.3376G>A p.G1126R | Missense Mutation (SNP) | VAF 75/246 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs775422043, COSV99454503; called by muse, mutect2, varscan2
- ALPP | c.610G>A p.G204R | Missense Mutation (SNP) | VAF 104/359 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs182497388; called by muse, mutect2, varscan2
- AMPD1 | c.826G>A p.D276N | Missense Mutation (SNP) | VAF 82/284 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs587779379, COSV62416273, COSV62417108; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD44 | c.2237G>A p.R746H | Missense Mutation (SNP) | VAF 97/351 reads (28%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.953); catalogued as rs766682314; called by muse, mutect2, varscan2
- APOB | c.13379G>A p.G4460E | Missense Mutation (SNP) | VAF 102/363 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1359515865; called by muse, mutect2, varscan2
- AQP10 | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 70/347 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs894944033, COSV61474436, COSV61474590, COSV61474821; called by muse, mutect2, varscan2
- ARHGEF35 | c.1285G>A p.V429M | Missense Mutation (SNP) | VAF 68/164 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs553072768, COSV100967808; called by muse, mutect2, varscan2
- ARR3 | c.623G>A p.G208E | Missense Mutation (SNP) | VAF 89/287 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99333667; called by muse, mutect2, varscan2
- ASB4 | c.1268G>A p.G423E | Missense Mutation (SNP) | VAF 66/330 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57945543; called by muse, mutect2, varscan2
- ASTN1 | c.2239G>A p.G747R | Missense Mutation (SNP) | VAF 84/326 reads (26%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.858); catalogued as COSV56062084; called by muse, mutect2, varscan2
- ATP6V0A4 | c.2309G>A p.R770Q | Missense Mutation (SNP) | VAF 91/404 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs991449515; called by muse, mutect2, varscan2
- ATP7A | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 105/362 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100430198; called by muse, mutect2, varscan2
- ATP9A | c.2504G>A p.S835N | Missense Mutation (SNP) | VAF 117/495 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.202); catalogued as rs1486554371; called by muse, mutect2, varscan2
- ATRIP | c.1112C>T p.S371F | Missense Mutation (SNP) | VAF 74/305 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); catalogued as COSV56498102; called by muse, mutect2, varscan2
- ATRN | c.949G>A p.G317R | Missense Mutation (SNP) | VAF 47/249 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.223); catalogued as rs1028043917; called by muse, mutect2, varscan2
- ATXN3 | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 58/217 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61497500; called by muse, mutect2, varscan2
- AUTS2 | c.3029C>T p.S1010F | Missense Mutation (SNP) | VAF 163/840 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.864); catalogued as rs375599992; called by muse, mutect2, varscan2
- BDKRB1 | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 147/418 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs1484829820, COSV99388079; called by muse, mutect2, varscan2
- BEND2 | c.1850C>T p.S617F | Missense Mutation (SNP) | VAF 139/451 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.063); catalogued as COSV66215344; called by muse, mutect2, varscan2
- BMP4 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 92/293 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753312749, COSV55415763; called by muse, mutect2, varscan2
- BRINP3 | c.2026G>A p.D676N | Missense Mutation (SNP) | VAF 108/499 reads (22%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.977); catalogued as COSV66515010; called by muse, mutect2, varscan2
- C1orf158 | c.355G>A p.G119R | Missense Mutation (SNP) | VAF 118/373 reads (32%) | SIFT tolerated (0.67); PolyPhen benign (0.017); catalogued as rs936863114; called by muse, mutect2, varscan2
- CACNA2D2 | c.34C>T p.R12W | Missense Mutation (SNP) | VAF 103/322 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.035); catalogued as rs1274971927; called by muse, mutect2, varscan2
- CATSPERB | c.2815G>A p.E939K | Missense Mutation (SNP) | VAF 84/241 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.621); catalogued as rs866205134, COSV56428671; called by muse, mutect2, varscan2
- CBLC | c.1301C>T p.P434L | Missense Mutation (SNP) | VAF 108/390 reads (28%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as COSV54324041, COSV54325367; called by muse, mutect2, varscan2
- CBX6 | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 219/739 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as rs1162602841; called by muse, mutect2, varscan2
- CCER1 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 149/471 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.209); catalogued as rs1335135329; called by muse, mutect2, varscan2
- CD163L1 | c.323G>A p.G108E | Missense Mutation (SNP) | VAF 88/277 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs75143024; called by muse, mutect2, varscan2
- CDH23 | c.367G>A p.G123R | Missense Mutation (SNP) | VAF 82/291 reads (28%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as rs727504513; ClinVar: uncertain significance; called by mutect2, varscan2
- CDON | c.2974C>T p.R992C | Missense Mutation (SNP) | VAF 67/232 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as rs1489303606; called by muse, varscan2
- CEACAM20 | c.1313C>T p.P438L | Missense Mutation (SNP) | VAF 75/221 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.601); catalogued as COSV57602923; called by muse, mutect2, varscan2
- CHPF | c.1255C>T p.R419W | Missense Mutation (SNP) | VAF 102/383 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs765155405; called by muse, mutect2, varscan2
- CHRNA4 | c.1168G>A p.G390R | Missense Mutation (SNP) | VAF 130/511 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.062); catalogued as COSV100937477; called by muse, mutect2, varscan2
- CHRNB3 | c.1208C>T p.S403L | Missense Mutation (SNP) | VAF 77/245 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as rs180939079, COSV51493304; called by muse, mutect2, varscan2
- CLIC6 | c.1810G>A p.D604N (on ENST00000360731 / NM_001317009.2; = p.D586N on NM_053277.3) | Missense Mutation (SNP) | VAF 82/281 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.901); catalogued as COSV62449796; called by muse, mutect2, varscan2
- CLSTN2 | c.2761G>A p.D921N | Missense Mutation (SNP) | VAF 134/456 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1314457372; called by muse, varscan2
- CNTNAP4 | c.3818G>A p.R1273K | Missense Mutation (SNP) | VAF 107/337 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56699535; called by muse, mutect2, varscan2
- COL11A1 | c.2764G>A p.G922R | Missense Mutation (SNP) | VAF 98/317 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62177368; called by muse, mutect2, varscan2
- COL1A1 | c.1546C>T p.P516S | Missense Mutation (SNP) | VAF 97/362 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.082); catalogued as rs750695521; called by muse, mutect2, varscan2
- COL22A1 | c.3251G>A p.G1084E | Missense Mutation (SNP) | VAF 122/392 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57324037; called by muse, mutect2
- COL4A2 | c.1162C>T p.P388S | Missense Mutation (SNP) | VAF 76/276 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs933951989; called by muse, mutect2, varscan2
- COL5A1 | c.2878C>T p.P960S | Missense Mutation (SNP) | VAF 95/326 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.196); catalogued as rs141301771, COSV65673913; called by muse, mutect2, varscan2
- COL6A3 | c.6428G>A p.G2143E | Missense Mutation (SNP) | VAF 101/305 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55091519; called by muse, mutect2, varscan2
- CSF1R | c.1717G>T p.E573* | Nonsense Mutation (SNP) | VAF 72/136 reads (53%) | catalogued as COSV53839956; called by muse, mutect2, varscan2
- CSMD1 | c.5899C>T p.P1967S (on ENST00000520002; = p.P1966S on NM_033225.6) | Missense Mutation (SNP) | VAF 70/270 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV59384557; called by muse, mutect2, varscan2
- CSMD3 | c.8662G>A p.G2888R (on ENST00000297405 / NM_001363185.1; = p.G2719R on NM_052900.3) | Missense Mutation (SNP) | VAF 91/305 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52127894; called by muse, mutect2, varscan2
- CSMD3 | c.772C>T p.P258S | Missense Mutation (SNP) | VAF 86/318 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV52164534; called by muse, mutect2, varscan2
- CT47B1 | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 135/469 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.087); catalogued as COSV64890661; called by muse, mutect2, varscan2
- CTNNA2 | c.1831G>A p.D611N | Missense Mutation (SNP) | VAF 110/345 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.246); catalogued as rs867688583; called by muse, mutect2, varscan2
- CTR9 | c.3012G>A p.M1004I | Missense Mutation (SNP) | VAF 57/226 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1341406586, COSV100797358; called by muse, mutect2, varscan2
- CYLC1 | c.1061del p.L354* | Frame Shift Del (DEL) | VAF 106/349 reads (30%) | catalogued as COSV61416679; called by mutect2, pindel, varscan2
- DACT1 | c.2030G>A p.R677Q | Missense Mutation (SNP) | VAF 138/431 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs746238004; called by muse, mutect2, varscan2
- DAPK1 | c.1291C>T p.L431F | Missense Mutation (SNP) | VAF 54/251 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV104419151, COSV63786777; called by muse, mutect2, varscan2
- DCDC2B | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 121/389 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as rs1376293322, COSV99356580; called by muse, mutect2, varscan2
- DEAF1 | c.1691C>T p.T564I | Missense Mutation (SNP) | VAF 94/303 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV99449011; called by muse, mutect2, varscan2
- DEFB106B | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 31/171 reads (18%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.021); catalogued as rs1340865148, COSV100128875; called by muse, mutect2, varscan2
- DGKZ | c.2461C>T p.P821S (on ENST00000454345 / NM_001105540.2; = p.P633S on NM_003646.4) | Missense Mutation (SNP) | VAF 17/358 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.54); catalogued as rs1435227259; called by muse, mutect2
- DHX35 | c.991G>C p.V331L | Missense Mutation (SNP) | VAF 161/322 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV52670036; called by muse, mutect2, varscan2
- DLEC1 | c.2685G>A p.M895I | Missense Mutation (SNP) | VAF 88/264 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV57303080; called by muse, mutect2, varscan2
- DMRT1 | c.734G>A p.G245E | Missense Mutation (SNP) | VAF 146/485 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as rs772628134; called by muse, mutect2, varscan2
- DNAH17 | c.8593G>A p.E2865K | Missense Mutation (SNP) | VAF 85/254 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs558955765, COSV67753634; called by muse, mutect2, varscan2
- DNAH8 | c.7514G>A p.R2505Q | Missense Mutation (SNP) | VAF 64/284 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1330298296, COSV59428426; called by muse, mutect2
- DNAH9 | c.6916G>A p.E2306K | Missense Mutation (SNP) | VAF 94/339 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV52332019; called by muse, mutect2, varscan2
- DSEL | c.2748G>A p.W916* | Nonsense Mutation (SNP) | VAF 111/376 reads (30%) | catalogued as COSV59489796; called by muse, mutect2, varscan2
- DYSF | c.6130C>T p.R2044W | Missense Mutation (SNP) | VAF 128/450 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs185617318; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EBF2 | c.1220G>A p.R407K | Missense Mutation (SNP) | VAF 150/379 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV68776992; called by muse, mutect2, varscan2
- EDAR | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 42/307 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as COSV51507818; called by muse, mutect2, varscan2
- EFCAB12 | c.1240C>T p.L414F | Missense Mutation (SNP) | VAF 53/207 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs868824912; called by muse, mutect2, varscan2
- EFHB | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 112/352 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.284); catalogued as COSV55545742; called by muse, mutect2, varscan2
- EIF3A | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 85/273 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64963109; called by muse, mutect2, varscan2
- ELN | c.1040C>T p.P347L | Missense Mutation (SNP) | VAF 20/766 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as CD994257; called by muse, mutect2
- ELN | c.2267G>A p.R756K (on ENST00000320399 / NM_001278939.1; = p.R723K on NM_000501.4) | Missense Mutation (SNP) | VAF 95/455 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV52709699; called by muse, mutect2, varscan2
- EPS8L2 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 132/446 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV59348655; called by muse, mutect2
- ERBB4 | c.2605G>A p.E869K | Missense Mutation (SNP) | VAF 99/313 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.316); catalogued as rs775232357; called by muse, mutect2, varscan2
- EVA1A | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 77/261 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs762669893, COSV52056518; called by muse, mutect2, varscan2
- F13A1 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 260/535 reads (49%) | SIFT tolerated (0.93); PolyPhen benign (0.166); catalogued as rs267601095, COSV53562294; called by muse, mutect2, varscan2
- F2 | c.1682G>A p.G561E | Missense Mutation (SNP) | VAF 100/302 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV56366999; called by muse, mutect2, varscan2
- FAM110B | c.404C>T p.S135L | Missense Mutation (SNP) | VAF 135/372 reads (36%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.953); catalogued as rs1018390985; called by muse, mutect2, varscan2
- FAM135B | c.2002G>A p.E668K | Missense Mutation (SNP) | VAF 120/394 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV52708881; called by muse, mutect2, varscan2
- FAM155B | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 188/546 reads (34%) | SIFT tolerated (0.83); PolyPhen benign (0.169); catalogued as COSV52935145; called by muse, mutect2
- FAM169A | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 74/230 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV65845876; called by muse, mutect2, varscan2
- FAM71F1 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 48/295 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as rs748384394; called by muse, mutect2, varscan2
- FANCB | c.89G>A p.G30E | Missense Mutation (SNP) | VAF 127/407 reads (31%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.986); catalogued as COSV60759545; called by muse, mutect2, varscan2
- FBXL7 | c.1027C>T p.R343W | Missense Mutation (SNP) | VAF 259/574 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs375745885; called by muse, mutect2, varscan2
- FCAMR | c.705G>A p.M235I | Missense Mutation (SNP) | VAF 90/404 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV61367003; called by muse, mutect2, varscan2
- FCRL5 | c.670C>T p.L224F | Missense Mutation (SNP) | VAF 225/478 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV62511475; called by muse, varscan2
- FGFR1 | c.1333C>T p.R445W (on ENST00000447712 / NM_023110.3; = p.R443W on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 123/370 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781608303, COSV58330773; called by muse, mutect2, varscan2
- FLG | c.5045G>A p.G1682E | Missense Mutation (SNP) | VAF 86/477 reads (18%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.671); catalogued as rs201238283; called by muse, mutect2, varscan2
- FLRT2 | c.65T>C p.I22T | Missense Mutation (SNP) | VAF 138/398 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV100421017; called by muse, mutect2, varscan2
- FSIP2 | c.5920G>A p.E1974K | Missense Mutation (SNP) | VAF 82/259 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs1402593727; called by muse, mutect2, varscan2
- GAB3 | c.1430G>A p.R477Q | Missense Mutation (SNP) | VAF 57/236 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.205); catalogued as rs1488680307, COSV65819055; called by muse, mutect2, varscan2
- GALNT14 | c.1555G>A p.D519N | Missense Mutation (SNP) | VAF 103/324 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs150328877; called by muse, mutect2, varscan2
- GALNT14 | c.895G>A p.D299N | Missense Mutation (SNP) | VAF 60/215 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61103968; called by muse, mutect2, varscan2
- GBE1 | c.1244C>T p.S415L | Missense Mutation (SNP) | VAF 84/226 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs766732933; called by muse, mutect2, varscan2
- GDAP1L1 | c.516G>A p.M172I | Missense Mutation (SNP) | VAF 104/384 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV61158848; called by muse, mutect2, varscan2
- GEMIN8 | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 182/477 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs1351066594, COSV60550895; called by muse, mutect2, varscan2
- GJB2 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 133/363 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67010714; called by muse, mutect2, varscan2
- GK2 | c.1567G>A p.D523N | Missense Mutation (SNP) | VAF 75/247 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs867193773; called by muse, mutect2, varscan2
- GLCE | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 80/306 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as rs892803570; called by muse, mutect2, varscan2
- GNB1L | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 217/465 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.316); catalogued as COSV61548066; called by muse, mutect2, varscan2
- GOLGA3 | c.1499C>T p.S500L | Missense Mutation (SNP) | VAF 147/433 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as rs774469337; called by muse, mutect2, varscan2
- GOLGA6L4 | c.1300G>T p.E434* | Nonsense Mutation (SNP) | VAF 34/182 reads (19%) | catalogued as rs780538719; called by muse, varscan2
- GOLIM4 | c.1981C>T p.R661* | Nonsense Mutation (SNP) | VAF 102/359 reads (28%) | catalogued as rs139759842; called by muse, mutect2, varscan2
- GOLT1A | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 103/337 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57643723; called by muse, mutect2, varscan2
- GPAM | c.913C>T p.R305* | Nonsense Mutation (SNP) | VAF 77/257 reads (30%) | catalogued as rs1312206205, COSV62080477; called by muse, mutect2, varscan2
- GPLD1 | c.1415C>T p.P472L | Missense Mutation (SNP) | VAF 101/386 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57759812; called by muse, mutect2, varscan2
- GPR50 | c.979C>T p.R327C | Missense Mutation (SNP) | VAF 170/514 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.528); catalogued as rs751147111, COSV54436892; called by muse, mutect2, varscan2
- GPRIN2 | c.449C>T p.P150L | Missense Mutation (SNP) | VAF 98/644 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as rs1555019549; called by muse, mutect2, varscan2
- GRB7 | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 129/345 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as rs150749308; called by muse, mutect2, varscan2
- GRIA4 | c.1862G>A p.R621Q | Missense Mutation (SNP) | VAF 67/215 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1304512680; called by muse, mutect2, varscan2
- GRID2 | c.1781G>A p.R594Q | Missense Mutation (SNP) | VAF 105/339 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.223); catalogued as rs1332581628, COSV56175430, COSV56182504; called by muse, mutect2, varscan2
- GRIP2 | c.2509+1G>A p.X837_splice (on ENST00000619221; = p.X740_splice on NM_001080423.4) | Splice Site (SNP) | VAF 76/186 reads (41%) | catalogued as rs925238713; called by muse, mutect2, varscan2
- GUCA2B | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 87/348 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as COSV65368288; called by muse, mutect2, varscan2
- GZMK | c.434C>T p.S145F | Missense Mutation (SNP) | VAF 137/442 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV99140827; called by muse, mutect2, varscan2
- HACE1 | c.1423C>T p.R475C | Missense Mutation (SNP) | VAF 122/282 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as rs142172304; called by muse, mutect2, varscan2
- HAUS3 | c.302A>T p.K101I | Missense Mutation (SNP) | VAF 86/281 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.026); catalogued as rs746037336; called by muse, mutect2, varscan2
- HCFC1 | c.2588C>T p.S863F | Missense Mutation (SNP) | VAF 151/473 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.88); catalogued as COSV60069835; called by muse, mutect2, varscan2
- HCK | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 141/309 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.047); catalogued as COSV52944614; called by muse, mutect2, varscan2
- HDAC9 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 296/484 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV101285689; called by muse, mutect2, varscan2
- HDAC9 | c.2353G>A p.E785K | Missense Mutation (SNP) | VAF 328/581 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV101286921; called by muse, mutect2, varscan2
- HGF | c.134C>T p.S45L | Missense Mutation (SNP) | VAF 92/469 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.424); catalogued as COSV55952685; called by muse, mutect2, varscan2
- HMX3 | c.704C>T p.S235L | Missense Mutation (SNP) | VAF 131/381 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372769291, COSV63501985; called by muse, mutect2, varscan2
- HTR5A | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 50/303 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV99839791; called by muse, mutect2, varscan2
- IGFN1 | c.3392C>T p.P1131L (on ENST00000295591 / NM_001367841.1; = p.P3588L on NM_001164586.2) | Missense Mutation (SNP) | VAF 101/465 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV55184786; called by muse, mutect2, varscan2
- IGSF1 | c.2729G>A p.G910E | Missense Mutation (SNP) | VAF 149/408 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs866816579; called by muse, mutect2, varscan2
- IGSF10 | c.5279G>A p.G1760E | Missense Mutation (SNP) | VAF 131/412 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56793291; called by muse, mutect2, varscan2
- IL37 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 60/246 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.022); catalogued as COSV54491645; called by muse, mutect2, varscan2
- IP6K1 | c.1160C>T p.P387L | Missense Mutation (SNP) | VAF 168/481 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.211); catalogued as rs948020062, COSV57696262; called by muse, mutect2, varscan2
- IQGAP2 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 87/286 reads (30%) | SIFT tolerated (0.86); PolyPhen benign (0.017); catalogued as COSV57167677, COSV57172210; called by muse, mutect2, varscan2
- IQGAP2 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 99/264 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV57168953; called by muse, mutect2, varscan2
- ISX | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 97/384 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1008666860; called by muse, varscan2
- ITGAD | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 89/272 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1369419074, COSV66756591; called by muse, mutect2, varscan2
- ITGBL1 | c.1060C>T p.R354C | Missense Mutation (SNP) | VAF 87/299 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.258); catalogued as rs745378521, COSV66008382, COSV66011885; called by muse, varscan2
- JDP2 | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 65/289 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.049); catalogued as rs1184369531; called by muse, mutect2, varscan2
- KAT14 | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 111/493 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.02); catalogued as rs368748280; called by muse, varscan2
- KCNB2 | c.1049C>T p.S350F | Missense Mutation (SNP) | VAF 121/355 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73050367; called by muse, mutect2, varscan2
- KCNH5 | c.2746G>A p.E916K | Missense Mutation (SNP) | VAF 138/389 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.777); catalogued as rs372872099; called by muse, mutect2, varscan2
- KDM6A | c.508C>T p.H170Y | Missense Mutation (SNP) | VAF 93/336 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV100938516; called by muse, mutect2, varscan2
- KDR | c.764G>A p.G255E | Missense Mutation (SNP) | VAF 94/277 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV55764799; called by muse, mutect2, varscan2
- KHDRBS2 | c.1034C>T p.P345L | Missense Mutation (SNP) | VAF 139/337 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99838625; called by muse, mutect2, varscan2
- KHDRBS2 | c.222C>T p.F74= | Splice Region (SNP) | VAF 117/262 reads (45%) | catalogued as rs914737061; called by muse, mutect2, varscan2
- KIAA0586 | c.1483C>T p.R495C (on ENST00000619416 / NM_001244190.2; = p.R510C on NM_014749.5) | Missense Mutation (SNP) | VAF 101/292 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs778123212, COSV54175650; called by muse, mutect2, varscan2
- KIAA1109 | c.11821C>T p.P3941S | Missense Mutation (SNP) | VAF 67/212 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as COSV52667259; called by muse, mutect2, varscan2
- KIAA1549 | c.5696C>T p.P1899L (on ENST00000422774 / NM_001164665.2; = p.P1883L on NM_020910.3) | Missense Mutation (SNP) | VAF 146/776 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as COSV54309410; called by muse, mutect2, varscan2
- KLK10 | c.661G>A p.G221S | Missense Mutation (SNP) | VAF 95/309 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as rs765078671; called by muse, mutect2, varscan2
- KLRC2 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 80/225 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.321); catalogued as rs777296375, COSV67899899; called by muse, varscan2
- KMT5B | c.2020G>A p.G674S | Missense Mutation (SNP) | VAF 100/333 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as rs758460246, COSV100430201; called by muse, mutect2, varscan2
- LAMA4 | c.4013C>T p.P1338L (on ENST00000230538 / NM_001105206.3; = p.P1331L on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 175/384 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs369532296; called by muse, mutect2, varscan2
- LAMA5 | c.10552del p.L3518Wfs*16 | Frame Shift Del (DEL) | VAF 124/566 reads (22%) | catalogued as rs1343598769; called by pindel, varscan2
- LELP1 | c.185C>A p.P62H | Missense Mutation (SNP) | VAF 125/648 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64202309; called by muse, mutect2, varscan2
- LGI1 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 84/277 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.257); catalogued as COSV65057438; called by muse, mutect2, varscan2
- LGMN | c.779C>T p.S260L | Missense Mutation (SNP) | VAF 97/323 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.08); catalogued as rs771834504, COSV58405338; called by muse, mutect2, varscan2
- LIPI | c.970C>T p.Q324* | Nonsense Mutation (SNP) | VAF 101/230 reads (44%) | catalogued as COSV60714809; called by muse, mutect2, varscan2
- LRP1B | c.2479G>A p.D827N | Missense Mutation (SNP) | VAF 68/188 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.205); catalogued as COSV67258949; called by muse, mutect2, varscan2
- LRP2 | c.2239G>A p.D747N | Missense Mutation (SNP) | VAF 103/353 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55543370; called by muse, mutect2, varscan2
- LRTM1 | c.460C>T p.Q154* | Nonsense Mutation (SNP) | VAF 84/270 reads (31%) | catalogued as COSV55516936, COSV55530779; called by muse, mutect2, varscan2
- LTA4H | c.1258A>G p.I420V | Missense Mutation (SNP) | VAF 67/250 reads (27%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs763238840; called by muse, mutect2, varscan2
- LTA4H | c.1058C>T p.S353L | Missense Mutation (SNP) | VAF 45/190 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.375); catalogued as rs753304100, COSV57382551; called by muse, mutect2, varscan2
- LTN1 | c.3212C>T p.S1071L | Missense Mutation (SNP) | VAF 58/173 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.041); catalogued as rs528676722; called by muse, mutect2, varscan2
- LY9 | c.1310C>T p.S437F | Missense Mutation (SNP) | VAF 85/371 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs199688790, COSV54432023; called by muse, mutect2, varscan2
- MAGEC3 | c.1414C>T p.Q472* | Nonsense Mutation (SNP) | VAF 145/475 reads (31%) | catalogued as rs1210749310, COSV53575606; called by muse, mutect2, varscan2
- MAML2 | c.2314C>T p.L772F | Missense Mutation (SNP) | VAF 66/222 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV73263191; called by muse, mutect2, varscan2
- MAP11 | c.688T>C p.F230L | Missense Mutation (SNP) | VAF 301/472 reads (64%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs1489029365; called by muse, mutect2, varscan2
- MARCHF11 | c.1135C>T p.R379W | Missense Mutation (SNP) | VAF 146/380 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs537978378, COSV60135731; called by muse, mutect2, varscan2
- MB21D2 | c.508C>T p.H170Y | Missense Mutation (SNP) | VAF 92/328 reads (28%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.932); catalogued as COSV66661672; called by muse, mutect2, varscan2
- MBL2 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 140/445 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV64758524; called by muse, mutect2, varscan2
- MCM8 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 231/494 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751117307, COSV54516288; called by muse, mutect2, varscan2
- MDGA2 | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 100/267 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV62080879; called by muse, mutect2, varscan2
- ME1 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 82/218 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as rs1024613609, COSV63838552; called by muse, mutect2, varscan2
- MED12 | c.740G>A p.G247E | Missense Mutation (SNP) | VAF 26/308 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV61338651; called by muse, mutect2
- MGAM | c.620G>A p.G207E | Missense Mutation (SNP) | VAF 348/595 reads (58%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as COSV71885040, COSV71885999; called by muse, mutect2, varscan2
- MGAM2 | c.3306G>A p.M1102I | Missense Mutation (SNP) | VAF 78/453 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.053); catalogued as rs867532916, COSV101522919; called by muse, mutect2, varscan2
- MKS1 | c.1511C>T p.S504F | Missense Mutation (SNP) | VAF 88/275 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV56597783; called by muse, mutect2, varscan2
- MLIP | c.185A>T p.E62V | Missense Mutation (SNP) | VAF 80/317 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs768253884; called by muse, mutect2, varscan2
- MMP24 | c.1577G>A p.G526E | Missense Mutation (SNP) | VAF 212/433 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55769658; called by muse, mutect2, varscan2
- MPND | c.944C>T p.P315L | Missense Mutation (SNP) | VAF 121/350 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV53657064; called by muse, mutect2, varscan2
- MROH2B | c.1046G>A p.R349K | Missense Mutation (SNP) | VAF 95/224 reads (42%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.987); catalogued as rs774757854; called by muse, varscan2
- MUC16 | c.33071G>A p.G11024E | Missense Mutation (SNP) | VAF 24/546 reads (4%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV67503737; called by muse, mutect2
- MUC16 | c.20411C>T p.S6804F | Missense Mutation (SNP) | VAF 86/334 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.457); catalogued as rs760170817, COSV67454892; called by muse, mutect2, varscan2
- MUC16 | c.18695C>T p.S6232L | Missense Mutation (SNP) | VAF 80/293 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs946042128; called by muse, mutect2, varscan2
- MUC16 | c.3656C>T p.P1219L | Missense Mutation (SNP) | VAF 122/356 reads (34%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.053); catalogued as rs370098137; called by muse, mutect2, varscan2
- MUC5B | c.6832G>A p.A2278T | Missense Mutation (SNP) | VAF 198/632 reads (31%) | SIFT tolerated (0.76); PolyPhen benign (0.027); catalogued as COSV71594622; called by muse, mutect2, varscan2
- MUSK | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 90/238 reads (38%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.782); catalogued as COSV51883020; called by muse, mutect2, varscan2
- MYH11 | c.5734G>A p.E1912K | Missense Mutation (SNP) | VAF 27/486 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1030614126; called by muse, mutect2
- MYLK3 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 150/432 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs561120067; called by muse, varscan2
- MYO1C | c.1993C>T p.R665C (on ENST00000648651 / NM_001080779.2; = p.R630C on NM_033375.5) | Missense Mutation (SNP) | VAF 110/328 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770632413, COSV62999529; called by muse, mutect2, varscan2
- MYOM1 | c.2273C>T p.S758L | Missense Mutation (SNP) | VAF 112/330 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.228); catalogued as rs376205950; called by muse, mutect2, varscan2
- NCAM1 | c.1825C>T p.Q609* (on ENST00000316851 / NM_181351.5; = p.Q599* on NM_000615.7) | Nonsense Mutation (SNP) | VAF 74/236 reads (31%) | catalogued as COSV57514833; called by muse, mutect2, varscan2
- NCKAP1L | c.310C>T p.H104Y | Missense Mutation (SNP) | VAF 89/285 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs867120923, COSV99515487; called by muse, mutect2, varscan2
- NDST4 | c.1068G>A p.G356= | Splice Region (SNP) | VAF 56/185 reads (30%) | catalogued as rs1175255305, COSV99997367; called by muse, mutect2, varscan2
- NDST4 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 128/375 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV52121427; called by muse, mutect2, varscan2
- NEURL1B | c.905C>T p.P302L | Missense Mutation (SNP) | VAF 144/266 reads (54%) | SIFT tolerated (0.14); PolyPhen benign (0.363); catalogued as rs1362391463; called by muse, mutect2, varscan2
- NFASC | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 176/371 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as rs1313443406, COSV100362558; called by muse, mutect2, varscan2
- NFASC | c.230G>A p.R77Q (on ENST00000339876 / NM_001378329.1; = p.R71Q on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 147/293 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs757003214, COSV58365309; called by muse, mutect2, varscan2
- NLRP4 | c.2890G>A p.E964K | Missense Mutation (SNP) | VAF 50/192 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.027); catalogued as COSV56713242; called by muse, mutect2, varscan2
- NOTCH2 | c.1162G>A p.A388T | Missense Mutation (SNP) | VAF 18/379 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.698); catalogued as rs1273608383; called by muse, mutect2
- OBSCN | c.9527C>T p.S3176F | Missense Mutation (SNP) | VAF 17/492 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.262); catalogued as COSV52752701; called by muse, mutect2
- ODAM | c.395C>T p.S132F | Missense Mutation (SNP) | VAF 70/224 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.712); catalogued as rs1185178628, COSV68572383; called by muse, mutect2, varscan2
- OR11G2 | c.21T>A p.N7K | Missense Mutation (SNP) | VAF 59/167 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as COSV62132800; called by mutect2, varscan2
- OR13C4 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 94/274 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as rs1389573026; called by muse, mutect2, varscan2
- OR13F1 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 113/350 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs868203542, COSV58250805; called by muse, mutect2, varscan2
- OR14K1 | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 98/386 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.61); catalogued as rs1023799609; called by muse, mutect2, varscan2
- OR2A25 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 113/571 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as COSV68717058; called by muse, mutect2, varscan2
- OR2F2 | c.86C>T p.S29F | Missense Mutation (SNP) | VAF 118/637 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV68832948; called by muse, mutect2, varscan2
- OR2T2 | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 341/1253 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100737693; called by muse, mutect2, varscan2
- OR4A16 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 113/357 reads (32%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.082); catalogued as rs575051490, COSV59042137; called by muse, mutect2, varscan2
- OR4C5 | c.365T>A p.L122H | Missense Mutation (SNP) | VAF 80/283 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as rs1179339996; called by muse, mutect2, varscan2
- OR4D10 | c.482C>T p.S161F | Missense Mutation (SNP) | VAF 86/284 reads (30%) | SIFT tolerated (0.77); PolyPhen benign (0.007); catalogued as COSV73259986; called by muse, mutect2, varscan2
- OR4M1 | c.597G>A p.M199I | Missense Mutation (SNP) | VAF 145/679 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV60059808; called by muse, mutect2, varscan2
- OR51B6 | c.143G>A p.R48K | Missense Mutation (SNP) | VAF 130/348 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66512640; called by muse, mutect2
- OR51E1 | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 95/314 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101211532, COSV67810131; called by muse, mutect2, varscan2
- OR52B4 | c.596G>T p.W199L | Missense Mutation (SNP) | VAF 109/301 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV68768623; called by muse, mutect2, varscan2
- OR52M1 | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 125/379 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as rs1442619258, COSV64171469; called by muse, mutect2, varscan2
- OR52N1 | c.349C>T p.L117F | Missense Mutation (SNP) | VAF 143/401 reads (36%) | SIFT tolerated (0.2); PolyPhen probably damaging (1); catalogued as COSV100398612; called by muse, mutect2, varscan2
- OR7D4 | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 100/344 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as COSV58072224; called by muse, mutect2, varscan2
- ORM2 | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 74/271 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as rs1451137490, COSV56335482; called by muse, mutect2, varscan2
- OTOF | c.5887C>T p.R1963C (on ENST00000272371 / NM_194248.3; = p.R1196C on NM_004802.4) | Missense Mutation (SNP) | VAF 129/409 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); catalogued as rs142720632; called by muse, mutect2, varscan2
- PAPPA2 | c.3662C>T p.S1221L | Missense Mutation (SNP) | VAF 162/312 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.206); catalogued as COSV62793093; called by muse, varscan2
- PBOV1 | c.281C>T p.S94L | Missense Mutation (SNP) | VAF 185/427 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.961); catalogued as COSV52473475; called by muse, mutect2, varscan2
- PCDH15 | c.5620G>A p.D1874N | Missense Mutation (SNP) | VAF 86/269 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs751570688, COSV57415229; called by muse, mutect2, varscan2
- PCDHGB1 | c.2405C>T p.S802L | Missense Mutation (SNP) | VAF 70/167 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs755324921, COSV99528458; called by muse, mutect2, varscan2
- PCLO | c.8810G>A p.R2937K | Missense Mutation (SNP) | VAF 314/559 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.136); catalogued as COSV100435407; called by muse, varscan2
- PDE1A | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 80/246 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.418); catalogued as rs760883561; called by muse, mutect2, varscan2
- PDE8B | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 96/287 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as rs777640717, COSV53739888; called by muse, mutect2, varscan2
- PDGFC | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 70/232 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV99924832; called by muse, mutect2, varscan2
- PDYN | c.751C>T p.L251F | Missense Mutation (SNP) | VAF 152/315 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs761506243, COSV54100713; called by muse, mutect2, varscan2
- PHACTR4 | c.1916G>A p.R639K (on ENST00000373839 / NM_001350159.2; = p.R649K on NM_023923.4) | Missense Mutation (SNP) | VAF 91/295 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs1234986907; called by muse, mutect2, varscan2
- PIAS4 | c.994C>T p.R332W | Missense Mutation (SNP) | VAF 70/253 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99518811; called by muse, mutect2, varscan2
- PIEZO2 | c.7015C>T p.R2339C | Missense Mutation (SNP) | VAF 62/208 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775464447, COSV53287135; called by muse, mutect2, varscan2
- PIK3R1 | c.1768C>T p.R590W (on ENST00000521381 / NM_181523.3; = p.R320W on NM_181504.4) | Missense Mutation (SNP) | VAF 99/263 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1289880098, COSV57127359; called by muse, mutect2, varscan2
- PIWIL2 | c.1694G>A p.G565E | Missense Mutation (SNP) | VAF 53/175 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100769150; called by muse, mutect2, varscan2
- PJA1 | c.254C>T p.S85L | Missense Mutation (SNP) | VAF 130/408 reads (32%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.978); catalogued as rs1434296387, COSV64052670; called by muse, mutect2, varscan2
- PLA2G12B | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 106/349 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs781543351, COSV65978427; called by muse, mutect2, varscan2
- PLA2G4F | c.1309G>A p.E437K | Missense Mutation (SNP) | VAF 106/337 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.286); catalogued as COSV51828979; called by muse, mutect2, varscan2
- PLCH2 | c.1918G>A p.D640N | Missense Mutation (SNP) | VAF 107/332 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs867099837, COSV99616276; called by muse, mutect2, varscan2
- PLCL1 | c.2684G>A p.R895Q | Missense Mutation (SNP) | VAF 56/189 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.418); catalogued as rs376271200, COSV101407204; called by muse, mutect2, varscan2
- PLEKHG4 | c.2767G>A p.E923K | Missense Mutation (SNP) | VAF 83/273 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV58573465; called by muse, mutect2, varscan2
- PLEKHG4B | c.1409G>A p.G470E (on ENST00000283426; = p.G826E on NM_052909.5) | Missense Mutation (SNP) | VAF 76/302 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.12); catalogued as COSV52055324, COSV52057063; called by muse, mutect2, varscan2
- POM121L12 | c.419G>A p.G140E | Missense Mutation (SNP) | VAF 146/822 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV68692907; called by muse, mutect2, varscan2
- POTEA | c.109G>A p.G37R | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.907); catalogued as rs1293031321; called by muse, mutect2, varscan2
- PRDM10 | c.2387C>T p.P796L | Missense Mutation (SNP) | VAF 93/335 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58800310; called by muse, mutect2, varscan2
- PRKAR2B | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 66/346 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.109); catalogued as rs775824400, COSV55924987; called by muse, mutect2, varscan2
- PRR5 | c.43C>T p.L15F (on ENST00000336985 / NM_181333.4; = p.L6F on NM_015366.4) | Missense Mutation (SNP) | VAF 221/424 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1374032754; called by muse, mutect2, varscan2
- PRRT4 | c.1586C>T p.P529L | Missense Mutation (SNP) | VAF 408/729 reads (56%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.943); catalogued as rs1196652268; called by muse, mutect2, varscan2
- PRUNE2 | c.2054C>T p.S685L | Missense Mutation (SNP) | VAF 66/245 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.085); catalogued as COSV65045792, COSV65047559; called by muse, mutect2, varscan2
- PTCHD1 | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 152/453 reads (34%) | SIFT tolerated (0.66); PolyPhen benign (0.009); catalogued as rs757295075, COSV101037691; called by muse, mutect2, varscan2
- PTGS1 | c.1317G>A p.M439I | Missense Mutation (SNP) | VAF 104/271 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1013695541, COSV99793201; called by muse, mutect2, varscan2
- PTPRD | c.1774G>A p.G592S | Missense Mutation (SNP) | VAF 101/324 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61932287; called by muse, mutect2, varscan2
- PTPRK | c.2407C>T p.R803* (on ENST00000368215 / NM_001291984.2; = p.R804* on NM_002844.4) | Nonsense Mutation (SNP) | VAF 109/503 reads (22%) | catalogued as COSV100950798; called by muse, mutect2, varscan2
- RALGAPA2 | c.1360G>C p.D454H | Missense Mutation (SNP) | VAF 110/435 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.372); catalogued as COSV52514989; called by muse, mutect2, varscan2
- RASGRP1 | c.1882G>A p.E628K | Missense Mutation (SNP) | VAF 57/207 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as rs1018024227; called by muse, mutect2, varscan2
- RAVER1 | c.1394C>T p.P465L | Missense Mutation (SNP) | VAF 156/470 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV53348873; called by muse, mutect2, varscan2
- RB1CC1 | c.4196C>T p.P1399L | Missense Mutation (SNP) | VAF 81/302 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as rs1002621210; called by muse, mutect2, varscan2
- RBM20 | c.1051G>A p.D351N | Missense Mutation (SNP) | VAF 113/303 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs372999896; called by muse, mutect2, varscan2
- RBM34 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 92/411 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as rs746050670, COSV64012539; called by muse, mutect2, varscan2
- RBM47 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 128/418 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.798); catalogued as rs868711273, COSV55932908; called by muse, mutect2, varscan2
- RGPD3 | c.5242G>A p.G1748R | Missense Mutation (SNP) | VAF 96/268 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.575); catalogued as rs1464743600; called by muse, mutect2, varscan2
- RGS7 | c.289C>T p.H97Y | Missense Mutation (SNP) | VAF 200/394 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58542358; called by muse, mutect2, varscan2
- RGSL1 | c.2786C>T p.S929F | Missense Mutation (SNP) | VAF 151/291 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as COSV104399737; called by muse, mutect2, varscan2
- RIC3 | c.911C>T p.S304F (on ENST00000309737 / NM_001206671.4; = p.S303F on NM_024557.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 75/264 reads (28%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.242); catalogued as rs761134805; called by muse, varscan2
- RIMBP2 | c.1774C>T p.H592Y | Missense Mutation (SNP) | VAF 138/422 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.132); catalogued as rs139183976; called by muse, mutect2, varscan2
- RIMS2 | c.4202G>A p.G1401E (on ENST00000666250 / NM_001348490.2; = p.G972E on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 71/228 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867105084, COSV51666954; called by muse, mutect2, varscan2
- RNASE11 | c.263G>A p.G88E | Missense Mutation (SNP) | VAF 84/277 reads (30%) | SIFT tolerated (0.6); PolyPhen benign (0.025); catalogued as COSV60087724; called by muse, mutect2
- RNF213 | c.7219G>A p.E2407K | Missense Mutation (SNP) | VAF 103/348 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.428); catalogued as rs757086130; called by muse, mutect2, varscan2
- ROBO2 | c.2188C>T p.R730C | Missense Mutation (SNP) | VAF 81/216 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs751993663; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RP1L1 | c.3913G>A p.E1305K | Missense Mutation (SNP) | VAF 142/414 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs367556246; called by muse, mutect2, varscan2
- RP1L1 | c.2726G>A p.R909K | Missense Mutation (SNP) | VAF 175/556 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.087); catalogued as COSV66758617; called by muse, mutect2, varscan2
- RTL1 | c.2429G>A p.R810Q | Missense Mutation (SNP) | VAF 99/363 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1009269166, COSV66016665; called by muse, mutect2, varscan2
- RUNX1T1 | c.496C>T p.H166Y (on ENST00000265814 / NM_001198628.1; = p.H139Y on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 95/260 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs868452433, COSV56137692, COSV99752362; called by muse, mutect2, varscan2
- SALL1 | c.2023C>T p.P675S | Missense Mutation (SNP) | VAF 112/369 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs868718687, COSV51753329, COSV51757244; called by muse, mutect2, varscan2
- SAMD9 | c.4172C>T p.A1391V | Missense Mutation (SNP) | VAF 106/505 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV66077544; called by muse, mutect2, varscan2
- SATB2 | c.1882A>G p.I628V | Missense Mutation (SNP) | VAF 120/386 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV53484340; called by muse, mutect2, varscan2
- SBK2 | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 119/359 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs552414979, COSV100705058; called by muse, mutect2, varscan2
- SCAMP1 | c.189A>G p.I63M | Missense Mutation (SNP) | VAF 100/319 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.184); catalogued as COSV100210347; called by muse, mutect2, varscan2
- SCN10A | c.3067G>A p.E1023K | Missense Mutation (SNP) | VAF 50/189 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.245); catalogued as rs772571344, COSV71860673; called by muse, mutect2, varscan2
- SCN10A | c.838G>C p.D280H | Missense Mutation (SNP) | VAF 69/210 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0.198); catalogued as rs1320222905; called by muse, mutect2, varscan2
- SDK1 | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 93/508 reads (18%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV101269580; called by muse, mutect2, varscan2
- SELL | c.1014G>A p.M338I (on ENST00000650983; = p.M325I on NM_000655.5) | Missense Mutation (SNP) | VAF 155/333 reads (47%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1416767802; called by muse, mutect2, varscan2
- SEMA4G | c.1628+7G>A | Splice Region (SNP) | VAF 78/247 reads (32%) | catalogued as rs754808483; called by muse, mutect2, varscan2
- SGK3 | c.1169C>T p.S390F | Missense Mutation (SNP) | VAF 108/323 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.532); catalogued as COSV61894079; called by muse, mutect2, varscan2
- SHANK1 | c.3727G>A p.E1243K | Missense Mutation (SNP) | VAF 123/386 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV99520634; called by muse, varscan2
- SIGLEC1 | c.2005C>T p.P669S | Missense Mutation (SNP) | VAF 50/486 reads (10%) | SIFT tolerated (0.87); PolyPhen benign (0.39); catalogued as rs745998527; called by muse, mutect2, varscan2
- SIGLEC12 | c.1055C>T p.T352I (on ENST00000291707 / NM_053003.4; = p.T234I on NM_033329.2) | Missense Mutation (SNP) | VAF 94/281 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.813); catalogued as rs1343938737, COSV99389321; called by muse, mutect2, varscan2
- SIGLEC5 | c.584C>T p.S195F | Missense Mutation (SNP) | VAF 154/474 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); catalogued as rs756464645; called by muse, mutect2, varscan2
- SKAP1 | c.179G>A p.G60E | Missense Mutation (SNP) | VAF 47/178 reads (26%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as rs751645756, COSV100411997; called by muse, mutect2, varscan2
- SLC17A9 | c.256C>T p.R86W | Missense Mutation (SNP) | VAF 65/296 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs748547693; called by muse, mutect2, varscan2
- SLC22A13 | c.1477G>A p.G493S | Missense Mutation (SNP) | VAF 157/447 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.821); catalogued as rs144451006, COSV61291789; called by muse, mutect2, varscan2
- SLC22A24 | c.1499C>T p.S500F | Missense Mutation (SNP) | VAF 92/331 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1202539636, COSV70300484; called by muse, mutect2, varscan2
- SLC22A7 | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 210/440 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65354064; called by muse, mutect2, varscan2
- SLC25A48 | c.916G>A p.E306K (on ENST00000650267; = p.T255= on NM_001349335.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/158 reads (44%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.454); catalogued as rs1297520179; called by muse, mutect2, varscan2
- SLC26A3 | c.1810T>C p.S604P | Missense Mutation (SNP) | VAF 90/503 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.904); catalogued as rs770244075; called by muse, mutect2, varscan2
- SLC5A5 | c.1783C>T p.P595S | Missense Mutation (SNP) | VAF 99/285 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV55834678; called by muse, mutect2, varscan2
- SLC5A8 | c.1099G>A p.D367N | Missense Mutation (SNP) | VAF 65/389 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1469591227, COSV101610568, COSV73310877; called by muse, mutect2, varscan2
- SLC6A11 | c.962G>A p.G321E | Missense Mutation (SNP) | VAF 76/273 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99594272; called by muse, mutect2, varscan2
- SLC8A1 | c.1786G>A p.E596K | Missense Mutation (SNP) | VAF 72/247 reads (29%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.776); catalogued as rs756189297, COSV60481812; called by muse, mutect2, varscan2
- SLC9A2 | c.1442C>T p.P481L | Missense Mutation (SNP) | VAF 57/195 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs752859008; called by muse, mutect2, varscan2
- SLC9C2 | c.190G>A p.G64R | Missense Mutation (SNP) | VAF 149/306 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62945212; called by muse, mutect2, varscan2
- SLIT2 | c.1118C>T p.S373F | Missense Mutation (SNP) | VAF 58/200 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV56561641; called by muse, mutect2, varscan2
- SLIT2 | c.3745G>A p.D1249N | Missense Mutation (SNP) | VAF 99/289 reads (34%) | SIFT tolerated (0.61); PolyPhen benign (0.159); catalogued as COSV56572020; called by muse, mutect2, varscan2
- SMG9 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 20/350 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99526653; called by muse, mutect2
- SNAP91 | c.1516C>T p.P506S | Missense Mutation (SNP) | VAF 230/493 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as rs565332143, COSV52118903; called by muse, mutect2, varscan2
- SORCS3 | c.2213G>A p.G738E | Missense Mutation (SNP) | VAF 96/328 reads (29%) | SIFT tolerated (0.9); PolyPhen benign (0.206); catalogued as COSV63793757, COSV63798375; called by muse, mutect2, varscan2
- SPAM1 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 113/576 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs1363591547; called by muse, mutect2, varscan2
- SPTBN4 | c.4628G>A p.R1543Q | Missense Mutation (SNP) | VAF 86/294 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.545); catalogued as rs779832728; called by muse, mutect2, varscan2
- SST | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 117/386 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV55030682; called by muse, mutect2, varscan2
- STAC | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 59/203 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs141518066, COSV56212162; called by muse, mutect2, varscan2
- STAP2 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 55/185 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.561); catalogued as COSV74075482; called by muse, mutect2, varscan2
- STARD9 | c.4984G>A p.A1662T | Missense Mutation (SNP) | VAF 57/375 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.24); catalogued as rs1566937401; called by muse, mutect2, varscan2
- STARD9 | c.7478C>T p.S2493F | Missense Mutation (SNP) | VAF 128/391 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.391); catalogued as COSV51914131; called by muse, mutect2, varscan2
- STC1 | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 83/243 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.049); catalogued as rs1260045910, COSV51688609; called by muse, mutect2, varscan2
- STRADA | c.400C>T p.R134* (on ENST00000336174 / NM_001363786.1; = p.R97* on NM_153335.6) | Nonsense Mutation (SNP) | VAF 109/327 reads (33%) | catalogued as rs763615123, COSV55562153; called by muse, mutect2, varscan2
- STXBP5L | c.1412G>A p.G471E | Missense Mutation (SNP) | VAF 58/206 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99871594; called by muse, mutect2, varscan2
- SUCNR1 | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 99/318 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs912471214; called by muse, mutect2, varscan2
- SULT1E1 | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 41/158 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as rs748563147, COSV56946046, COSV56947939, COSV99895050; called by muse, mutect2, varscan2
- SYNE1 | c.2806C>T p.R936* (on ENST00000367255 / NM_182961.4; = p.R943* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 206/451 reads (46%) | catalogued as rs1284888928, COSV55043531; called by muse, mutect2, varscan2
- SYNE1 | c.2326G>A p.E776K (on ENST00000367255 / NM_182961.4; = p.E783K on NM_033071.3) | Missense Mutation (SNP) | VAF 19/570 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV55060564; called by muse, mutect2
- SYNPO2 | c.2330C>T p.S777F | Missense Mutation (SNP) | VAF 146/425 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61109301; called by muse, mutect2, varscan2
- TBC1D5 | c.1778C>T p.S593F | Missense Mutation (SNP) | VAF 54/201 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs866613522, COSV53750594; called by muse, mutect2, varscan2
- TCL1B | c.86G>A p.G29E | Missense Mutation (SNP) | VAF 105/391 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.881); catalogued as COSV100525732; called by muse, mutect2, varscan2
- TDRD5 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 129/305 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as COSV54238766; called by muse, mutect2, varscan2
- TEKT5 | c.977C>T p.T326I | Missense Mutation (SNP) | VAF 108/353 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.039); catalogued as rs1023255999; called by muse, mutect2, varscan2
- TEX15 | c.8351C>T p.S2784F (on ENST00000256246; = p.S3167F on NM_001350162.2) | Missense Mutation (SNP) | VAF 63/210 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.66); catalogued as COSV56350529; called by muse, mutect2, varscan2
- TGM1 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 101/300 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0.306); catalogued as rs150181059; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- THSD7A | c.1771G>A p.E591K | Missense Mutation (SNP) | VAF 60/776 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs748075499, COSV101448629; called by muse, mutect2
- THSD7A | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 98/510 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.03); catalogued as rs770834772, COSV70267932; called by muse, mutect2, varscan2
- TLR4 | c.1037C>T p.P346L (on ENST00000355622 / NM_138554.5; = p.P306L on NM_003266.4) | Missense Mutation (SNP) | VAF 69/252 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV62922418; called by muse, mutect2, varscan2
- TLR4 | c.1282G>A p.D428N (on ENST00000355622 / NM_138554.5; = p.D388N on NM_003266.4) | Missense Mutation (SNP) | VAF 102/363 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs376443096, COSV62922367; called by muse, mutect2, varscan2
- TMEM132D | c.2179G>A p.D727N | Missense Mutation (SNP) | VAF 100/344 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.314); catalogued as rs546922206, COSV101242874, COSV67160502; called by muse, mutect2, varscan2
- TMEM26 | c.1057C>T p.P353S | Missense Mutation (SNP) | VAF 116/344 reads (34%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.031); catalogued as COSV53262749; called by muse, mutect2, varscan2
- TNC | c.4472G>A p.R1491Q | Missense Mutation (SNP) | VAF 100/292 reads (34%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); catalogued as rs189247379; called by muse, mutect2, varscan2
- TOP2B | c.3541C>T p.P1181S (on ENST00000264331 / NM_001330700.2; = p.P1176S on NM_001068.3) | Missense Mutation (SNP) | VAF 63/239 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.133); catalogued as rs1441188108; called by muse, mutect2, varscan2
- TPTE | c.1138G>A p.E380K (on ENST00000618007 / NM_199261.4; = p.E362K on NM_199259.4) | Missense Mutation (SNP) | VAF 40/249 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as rs781489069; called by muse, mutect2, varscan2
- TRAV26-1 | c.81G>A p.M27I | Missense Mutation (SNP) | VAF 95/249 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.03); catalogued as rs1157258276; called by muse, mutect2, varscan2
- TRAV38-2DV8 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 106/323 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as rs953033974; called by muse, mutect2, varscan2
- TTN | c.79631G>A p.R26544Q (on ENST00000591111; = p.R19120Q on NM_003319.4) | Missense Mutation (SNP) | VAF 105/361 reads (29%) | PolyPhen benign (0); catalogued as rs371516793; called by muse, mutect2, varscan2
- TTN | c.24814G>A p.E8272K (on ENST00000591111; = p.E7345K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 96/291 reads (33%) | PolyPhen benign (0.007); catalogued as COSV60072415; called by muse, mutect2, varscan2
- TXNRD3 | c.1531C>T p.H511Y (on ENST00000523403 / NM_001173513.2; = p.H547Y on NM_052883.2) | Missense Mutation (SNP) | VAF 61/180 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV67312036; called by muse, mutect2, varscan2
- UFL1 | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 82/380 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as rs761235969, COSV65150590; called by muse, mutect2, varscan2
- USH1G | c.148C>T p.L50F | Missense Mutation (SNP) | VAF 91/295 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs1347555949; called by muse, mutect2, varscan2
- USP43 | c.1418C>T p.P473L | Missense Mutation (SNP) | VAF 93/295 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1227097879, COSV53302127; called by muse, mutect2, varscan2
- USPL1 | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 66/208 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV54999167; called by muse, mutect2, varscan2
- VEGFC | c.1034G>A p.R345K | Missense Mutation (SNP) | VAF 97/349 reads (28%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV54598829, COSV99709435; called by muse, mutect2, varscan2
- VPS13A | c.2975C>T p.S992F | Missense Mutation (SNP) | VAF 41/165 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1393392826, COSV62440263; called by muse, mutect2, varscan2
- VSIG2 | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761373419; called by muse, mutect2, varscan2
- VSIG2 | c.430C>T p.P144S | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs764844490, COSV52518261; called by muse, mutect2, varscan2
- WDFY4 | c.2140G>A p.D714N | Missense Mutation (SNP) | VAF 145/400 reads (36%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.915); catalogued as rs1439446294; called by muse, mutect2, varscan2
- XK | c.782C>T p.S261F | Missense Mutation (SNP) | VAF 126/416 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1414126215; called by muse, mutect2, varscan2
- YME1L1 | c.1415C>T p.P472L (on ENST00000326799 / NM_139312.3; = p.P415L on NM_014263.4) | Missense Mutation (SNP) | VAF 46/173 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.143); catalogued as COSV100464271, COSV58761578; called by muse, mutect2, varscan2
- ZAN | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 260/760 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.542); catalogued as COSV61808807; called by muse, mutect2, varscan2
- ZBED9 | c.1844G>A p.S615N | Missense Mutation (SNP) | VAF 149/623 reads (24%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs754439812; called by muse, mutect2, varscan2
- ZBP1 | c.1046C>T p.P349L | Missense Mutation (SNP) | VAF 207/469 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.099); catalogued as rs755388299; called by muse, mutect2, varscan2
- ZFHX3 | c.8083C>T p.R2695W | Missense Mutation (SNP) | VAF 117/368 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs142218077; called by muse, mutect2, varscan2
- ZFP69B | c.1069C>T p.H357Y | Missense Mutation (SNP) | VAF 129/388 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1418459695, COSV64315354; called by muse, mutect2, varscan2
- ZNF165 | c.1154C>T p.S385L | Missense Mutation (SNP) | VAF 103/420 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as COSV66102394, COSV66102896; called by muse, mutect2, varscan2
- ZNF331 | c.589C>T p.R197* | Nonsense Mutation (SNP) | VAF 112/344 reads (33%) | catalogued as COSV53480322; called by muse, mutect2, varscan2
- ZNF726 | c.302G>A p.R101K | Missense Mutation (SNP) | VAF 80/194 reads (41%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.753); catalogued as rs561867774; called by muse, mutect2, varscan2
- ZNF780B | c.2125C>T p.H709Y | Missense Mutation (SNP) | VAF 99/317 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as COSV55464154, COSV99665176; called by muse, mutect2, varscan2
- ZNF781 | c.331C>T p.H111Y | Missense Mutation (SNP) | VAF 124/355 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1476560461, COSV62203202; called by muse, mutect2, varscan2
- ZNF80 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 131/368 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.352); catalogued as COSV100352108; called by muse, mutect2, varscan2
- ZP1 | c.488C>T p.S163F | Missense Mutation (SNP) | VAF 129/390 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV53927054; called by muse, mutect2, varscan2
- ZSWIM2 | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 80/244 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1294263745, COSV54579553, COSV99720609; called by muse, mutect2, varscan2
- ABCA12 | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 67/202 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- ABCA13 | c.4148C>T p.S1383F | Missense Mutation (SNP) | VAF 232/378 reads (61%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ABCA7 | c.5369_5371del p.G1790del | In Frame Del (DEL) | VAF 95/328 reads (29%) | called by mutect2, pindel, varscan2
- ABCB11 | c.3002G>A p.R1001K | Missense Mutation (SNP) | VAF 96/326 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- ABL1 | c.1949C>T p.P650L | Missense Mutation (SNP) | VAF 143/428 reads (33%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ABLIM2 | c.883C>T p.P295S | Missense Mutation (SNP) | VAF 40/441 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); called by muse, mutect2
- ACE2 | c.1690G>A p.E564K | Missense Mutation (SNP) | VAF 87/295 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ACTN3 | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 116/336 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- ADAM22 | c.2315G>A p.G772E | Missense Mutation (SNP) | VAF 61/378 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- ADAM29 | c.1202G>A p.G401E | Missense Mutation (SNP) | VAF 121/434 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS3 | c.358A>G p.I120V | Missense Mutation (SNP) | VAF 125/411 reads (30%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADCY1 | c.1568C>T p.P523L | Missense Mutation (SNP) | VAF 80/488 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ADD2 | c.1805T>G p.V602G | Missense Mutation (SNP) | VAF 31/441 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.009); called by muse, mutect2
- ADGRG4 | c.1850G>A p.G617E | Missense Mutation (SNP) | VAF 139/395 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AFF4 | c.3355G>A p.E1119K | Missense Mutation (SNP) | VAF 70/141 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- AIM2 | c.920G>A p.G307E | Missense Mutation (SNP) | VAF 252/487 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- AKR1D1 | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 224/394 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- AL353572.3 | c.103C>T p.Q35* | Nonsense Mutation (SNP) | VAF 75/287 reads (26%) | called by muse, mutect2, varscan2
- ALMS1 | c.8032C>T p.P2678S | Missense Mutation (SNP) | VAF 56/350 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- ANAPC2 | c.1466C>T p.P489L | Missense Mutation (SNP) | VAF 65/209 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- ANAPC2 | c.959C>T p.T320I | Missense Mutation (SNP) | VAF 113/370 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ANPEP | c.718C>T p.P240S | Missense Mutation (SNP) | VAF 112/338 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- APOBEC1 | c.124A>G p.I42V | Missense Mutation (SNP) | VAF 87/300 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- AR | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 157/516 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARFGEF3 | c.1196C>T p.S399F | Missense Mutation (SNP) | VAF 52/324 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- ARHGEF15 | c.1889C>T p.S630F | Missense Mutation (SNP) | VAF 107/383 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARPP21 | c.2197G>A p.G733S | Missense Mutation (SNP) | VAF 71/247 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- ARRB2 | c.1168G>A p.D390N | Missense Mutation (SNP) | VAF 63/226 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ASAH2 | c.1130C>T p.P377L | Missense Mutation (SNP) | VAF 15/320 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); called by muse, mutect2
- AVEN | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 53/155 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- AWAT2 | c.784G>A p.G262R | Missense Mutation (SNP) | VAF 140/466 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- BANK1 | c.688T>A p.F230I | Missense Mutation (SNP) | VAF 101/312 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BCO1 | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 105/286 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- BCORL1 | c.3079C>T p.P1027S | Missense Mutation (SNP) | VAF 148/497 reads (30%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- BTBD11 | c.1121G>A p.G374E | Missense Mutation (SNP) | VAF 61/157 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BTN1A1 | c.1175G>A p.G392E | Missense Mutation (SNP) | VAF 269/541 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C1R | c.100C>T p.P34S (on ENST00000536053 / NM_001354346.2; = p.P20S on NM_001733.7) | Missense Mutation (SNP) | VAF 116/340 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- C6orf118 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 28/340 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.592); called by muse, mutect2
- C9orf135 | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 71/214 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- CACNA1C | c.5309C>T p.A1770V | Missense Mutation (SNP) | VAF 131/410 reads (32%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- CACNA1G | c.1564C>T p.Q522* | Nonsense Mutation (SNP) | VAF 146/453 reads (32%) | called by muse, varscan2
- CACNG8 | c.743G>A p.G248D | Missense Mutation (SNP) | VAF 143/438 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- CAMTA1 | c.2048C>T p.A683V | Missense Mutation (SNP) | VAF 119/372 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- CAP2 | c.682G>A p.G228R | Missense Mutation (SNP) | VAF 139/508 reads (27%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- CAPS2 | c.596G>A p.G199D | Missense Mutation (SNP) | VAF 81/266 reads (30%) | SIFT tolerated (0.73); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- CATSPERE | c.1369G>A p.G457R | Missense Mutation (SNP) | VAF 43/408 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.108); called by muse, mutect2
- CATSPERG | c.2570C>T p.S857F | Missense Mutation (SNP) | VAF 100/328 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- CC2D2B | c.827C>T p.S276L | Missense Mutation (SNP) | VAF 54/210 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- CCBE1 | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 128/414 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CCDC168 | c.1465C>T p.L489F | Missense Mutation (SNP) | VAF 81/290 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- CCDC71 | c.527C>T p.S176F | Missense Mutation (SNP) | VAF 150/437 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC83 | c.1106G>A p.G369E (on ENST00000342404 / NM_001286159.2; = p.G400E on NM_173556.5) | Missense Mutation (SNP) | VAF 92/276 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH23 | c.368G>A p.G123E | Missense Mutation (SNP) | VAF 84/298 reads (28%) | SIFT tolerated (0.27); PolyPhen probably damaging (1); called by mutect2, varscan2
- CDH23 | c.3382G>A p.D1128N | Missense Mutation (SNP) | VAF 115/403 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- CDH23 | c.4138G>A p.E1380K | Missense Mutation (SNP) | VAF 125/379 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDH6 | c.1307G>A p.G436E | Missense Mutation (SNP) | VAF 96/369 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- CEACAM5 | c.596C>T p.T199I | Missense Mutation (SNP) | VAF 139/428 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CERKL | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- CFAP46 | c.8077C>T p.P2693S | Missense Mutation (SNP) | VAF 130/370 reads (35%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFAP54 | c.5663G>A p.R1888K | Missense Mutation (SNP) | VAF 99/321 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- CFAP91 | c.250C>T p.P84S | Missense Mutation (SNP) | VAF 70/246 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CFHR4 | c.1714G>A p.E572K (on ENST00000367416 / NM_001201551.2; = p.E326K on NM_006684.5) | Missense Mutation (SNP) | VAF 113/321 reads (35%) | SIFT tolerated (0.86); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CGREF1 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 219/613 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- CHRM5 | c.1448T>C p.L483S | Missense Mutation (SNP) | VAF 117/417 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHRNB4 | c.522G>A p.W174* | Nonsense Mutation (SNP) | VAF 126/395 reads (32%) | called by muse, mutect2, varscan2
- CHST9 | c.872G>A p.R291K | Missense Mutation (SNP) | VAF 90/309 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- CHSY3 | c.1834del p.E612Kfs*24 | Frame Shift Del (DEL) | VAF 84/292 reads (29%) | called by mutect2, pindel, varscan2
- CHSY3 | c.2383G>A p.G795R | Missense Mutation (SNP) | VAF 140/362 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHSY3 | c.2527G>A p.D843N | Missense Mutation (SNP) | VAF 101/326 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- CLCA4 | c.1162G>A p.G388R | Missense Mutation (SNP) | VAF 53/208 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNNM1 | c.896G>A p.G299D | Missense Mutation (SNP) | VAF 138/435 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- CNTN2 | c.2684G>A p.G895D | Missense Mutation (SNP) | VAF 145/570 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNTRL | c.5918A>G p.E1973G | Missense Mutation (SNP) | VAF 96/334 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.058); called by muse, varscan2
- COL5A1 | c.1729G>A p.G577R | Missense Mutation (SNP) | VAF 95/271 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CPNE5 | c.1393A>G p.I465V | Missense Mutation (SNP) | VAF 82/391 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- CPNE6 | c.1607G>A p.S536N | Missense Mutation (SNP) | VAF 128/413 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CROCC | c.198C>T p.V66= | Splice Region (SNP) | VAF 66/305 reads (22%) | called by muse, mutect2, varscan2
- CTRC | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 144/393 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CYP11B1 | c.238A>G p.R80G | Missense Mutation (SNP) | VAF 89/252 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- DDX52 | c.364C>T p.Q122* | Nonsense Mutation (SNP) | VAF 46/167 reads (28%) | called by muse, mutect2, varscan2
- DDX60L | c.4997C>T p.S1666F | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- DHCR24 | c.1067G>A p.G356D | Missense Mutation (SNP) | VAF 100/340 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- DHX33 | c.1810T>A p.L604I | Missense Mutation (SNP) | VAF 64/240 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DIRAS3 | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 117/285 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- DISP3 | c.2143G>A p.E715K | Missense Mutation (SNP) | VAF 114/385 reads (30%) | SIFT tolerated (0.64); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- DKK4 | c.111+1G>A p.X37_splice | Splice Site (SNP) | VAF 10/254 reads (4%) | called by muse, mutect2
- DNAH12 | c.4039C>T p.P1347S (on ENST00000351747; = p.P1370S on NM_001366028.2) | Missense Mutation (SNP) | VAF 85/244 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- DNAH14 | c.8359G>A p.D2787N (on ENST00000445597; = p.D3590N on NM_001367479.1) | Missense Mutation (SNP) | VAF 56/313 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DNAH2 | c.6808G>A p.D2270N | Missense Mutation (SNP) | VAF 113/380 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- DNAH3 | c.4249G>A p.G1417R | Missense Mutation (SNP) | VAF 63/248 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH9 | c.8668G>A p.E2890K | Missense Mutation (SNP) | VAF 63/250 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DNAJB6 | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 128/750 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- DPP10 | c.1095T>A p.D365E | Missense Mutation (SNP) | VAF 110/328 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DPPA5 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 88/366 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- DPYS | c.823G>A p.A275T | Missense Mutation (SNP) | VAF 68/253 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- DSG3 | c.2318G>A p.G773E | Missense Mutation (SNP) | VAF 135/378 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- DSP | c.2060C>T p.T687I | Missense Mutation (SNP) | VAF 240/437 reads (55%) | SIFT tolerated (0.42); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- DUOX2 | c.2602G>A p.D868N | Missense Mutation (SNP) | VAF 100/291 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EGFLAM | c.1318C>A p.L440M | Missense Mutation (SNP) | VAF 25/474 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- ELP2 | c.1535-1G>A p.X512_splice | Splice Site (SNP) | VAF 7/180 reads (4%) | called by muse, mutect2
- EML6 | c.1933G>A p.V645I | Missense Mutation (SNP) | VAF 54/168 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EML6 | c.4115G>A p.R1372K | Missense Mutation (SNP) | VAF 73/238 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ENTPD1 | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 25/371 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EPB41L3 | c.548C>T p.S183L | Missense Mutation (SNP) | VAF 57/204 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- EPB41L4B | c.1627C>T p.L543F | Missense Mutation (SNP) | VAF 62/250 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- EPB41L5 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 101/304 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- EPHA6 | c.2545G>A p.E849K (on ENST00000389672 / NM_001080448.3; = p.E241K on NM_173655.4) | Missense Mutation (SNP) | VAF 18/381 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- ERBIN | c.3317C>T p.S1106L | Missense Mutation (SNP) | VAF 98/285 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- EVPL | c.4564G>A p.E1522K | Missense Mutation (SNP) | VAF 20/463 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- EXOC4 | c.2435C>T p.P812L | Missense Mutation (SNP) | VAF 52/525 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- FAM155B | c.247G>A p.G83R | Missense Mutation (SNP) | VAF 99/366 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM160A2 | c.1898C>T p.P633L (on ENST00000449352 / NM_001098794.2; = p.P647L on NM_032127.4) | Missense Mutation (SNP) | VAF 16/418 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- FAM163B | c.218A>G p.Y73C | Missense Mutation (SNP) | VAF 120/455 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FAM169A | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 69/201 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- FAM186A | c.2840G>A p.R947K | Missense Mutation (SNP) | VAF 127/403 reads (32%) | SIFT tolerated (0.71); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM217A | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 125/323 reads (39%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- FAM234A | c.1191C>T p.I397= | Splice Region (SNP) | VAF 81/211 reads (38%) | called by muse, mutect2, varscan2
- FBXO38 | c.2509A>T p.S837C | Missense Mutation (SNP) | VAF 119/247 reads (48%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- FBXW11 | c.1010C>T p.S337F | Missense Mutation (SNP) | VAF 93/217 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FCAR | c.175C>T p.Q59* | Nonsense Mutation (SNP) | VAF 199/636 reads (31%) | called by muse, mutect2, varscan2
- FHOD3 | c.2936C>T p.P979L (on ENST00000359247 / NM_001281739.3; = p.P996L on NM_025135.5) | Missense Mutation (SNP) | VAF 118/412 reads (29%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FIBCD1 | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 144/410 reads (35%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- FLG2 | c.1454G>A p.G485D | Missense Mutation (SNP) | VAF 23/574 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.051); called by muse, mutect2
- FLNC | c.6485G>A p.G2162E | Missense Mutation (SNP) | VAF 228/374 reads (61%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- FOXD4L5 | c.832T>A p.Y278N | Missense Mutation (SNP) | VAF 110/656 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- FOXD4L6 | c.832T>A p.Y278N | Missense Mutation (SNP) | VAF 46/819 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.212); called by muse, mutect2
- FRAS1 | c.5217G>A p.V1739= | Splice Region (SNP) | VAF 14/205 reads (7%) | called by muse, mutect2
- FRAS1 | c.9293G>A p.S3098N | Missense Mutation (SNP) | VAF 95/287 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FREM1 | c.4282G>A p.E1428K | Missense Mutation (SNP) | VAF 122/406 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- FREM3 | c.1465G>A p.G489R | Missense Mutation (SNP) | VAF 133/383 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- FRMD3 | c.1586C>T p.S529F | Missense Mutation (SNP) | VAF 119/359 reads (33%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- FSD2 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 86/289 reads (30%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- FSIP2 | c.3062_3063dup p.D1022Kfs*5 | Frame Shift Ins (INS) | VAF 56/209 reads (27%) | called by mutect2, pindel, varscan2
- GBF1 | c.2608C>T p.Q870* (on ENST00000369983 / NM_001377137.1; = p.Q869* on NM_004193.3) | Nonsense Mutation (SNP) | VAF 83/297 reads (28%) | called by muse, mutect2, varscan2
- GDA | c.1021G>A p.D341N | Missense Mutation (SNP) | VAF 104/290 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- GDF1 | c.580G>C p.V194L | Missense Mutation (SNP) | VAF 68/295 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GOLGA6A | c.1495G>A p.G499R | Missense Mutation (SNP) | VAF 95/798 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- GPATCH1 | c.2282C>T p.S761F | Missense Mutation (SNP) | VAF 90/319 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GPBAR1 | c.854A>G p.Q285R | Missense Mutation (SNP) | VAF 139/460 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPRASP2 | c.1832C>T p.P611L | Missense Mutation (SNP) | VAF 105/323 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPRC5C | c.208G>A p.G70S (on ENST00000652232; = p.G25S on NM_018653.4) | Missense Mutation (SNP) | VAF 120/378 reads (32%) | SIFT tolerated (0.84); PolyPhen benign (0.001); called by muse, varscan2
- GPRC5C | c.295G>A p.E99K (on ENST00000652232; = p.E54K on NM_018653.4) | Missense Mutation (SNP) | VAF 126/404 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.485); called by muse, varscan2
- GRB2 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 10/326 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GRIA2 | c.1551G>A p.M517I | Missense Mutation (SNP) | VAF 84/275 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- GRM6 | c.1708G>A p.G570S | Missense Mutation (SNP) | VAF 138/286 reads (48%) | SIFT tolerated (0.34); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GSTA3 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 209/443 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- HCN4 | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HDAC9 | c.2735G>A p.G912E | Missense Mutation (SNP) | VAF 173/482 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HECW1 | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 202/526 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HECW1 | c.945G>T p.G315= | Splice Region (SNP) | VAF 62/316 reads (20%) | called by muse, mutect2, varscan2
- HHIPL1 | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 123/402 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HSD17B13 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 77/247 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- HSPB11 | c.373C>T p.H125Y | Missense Mutation (SNP) | VAF 100/293 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- HSPB2 | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 94/289 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HTR3E | c.152G>A p.R51K (on ENST00000415389 / NM_001256613.1; = p.R66K on NM_182589.2) | Missense Mutation (SNP) | VAF 106/349 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- IL17RA | c.1343C>T p.S448F | Missense Mutation (SNP) | VAF 141/542 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- INPP5J | c.1251G>A p.W417* | Nonsense Mutation (SNP) | VAF 93/480 reads (19%) | called by muse, mutect2, varscan2
- INTS1 | c.329C>T p.P110L | Missense Mutation (SNP) | VAF 84/429 reads (20%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- IRF2BPL | c.793C>T p.P265S | Missense Mutation (SNP) | VAF 97/280 reads (35%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ISX | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 138/310 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.006); called by muse, mutect2
- KANSL1 | c.1308G>A p.W436* | Nonsense Mutation (SNP) | VAF 92/376 reads (24%) | called by muse, mutect2, varscan2
- KAT6B | c.2974A>G p.I992V | Missense Mutation (SNP) | VAF 84/267 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KDM7A | c.391T>C p.F131L | Missense Mutation (SNP) | VAF 76/399 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KNDC1 | c.1979G>C p.G660A | Missense Mutation (SNP) | VAF 167/520 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KRBA1 | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 93/444 reads (21%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- LAMB4 | c.3207G>A p.W1069* | Nonsense Mutation (SNP) | VAF 183/482 reads (38%) | called by muse, mutect2, varscan2
- LCT | c.3183G>A p.M1061I | Missense Mutation (SNP) | VAF 118/320 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- LGR5 | c.2131C>T p.L711F | Missense Mutation (SNP) | VAF 96/375 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- LMBRD2 | c.1957C>T p.Q653* | Nonsense Mutation (SNP) | VAF 78/312 reads (25%) | called by muse, varscan2
- LPA | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 46/234 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- LRCH2 | c.1033C>T p.P345S | Missense Mutation (SNP) | VAF 73/274 reads (27%) | SIFT tolerated (0.82); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LRIT1 | c.1025C>T p.S342F | Missense Mutation (SNP) | VAF 79/436 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- LRIT2 | c.742A>G p.S248G | Missense Mutation (SNP) | VAF 125/374 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRC4C | c.719A>G p.Q240R | Missense Mutation (SNP) | VAF 158/411 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LYPD8 | c.569G>A p.G190E | Missense Mutation (SNP) | VAF 127/466 reads (27%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAGEE1 | c.1813G>A p.E605K | Missense Mutation (SNP) | VAF 144/456 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- MAGI2 | c.3458G>A p.G1153E | Missense Mutation (SNP) | VAF 54/628 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2
- MALRD1 | c.398G>A p.R133K | Missense Mutation (SNP) | VAF 81/244 reads (33%) | SIFT tolerated (0.88); PolyPhen benign (0.212); called by mutect2, varscan2
- MAOA | c.494G>A p.C165Y | Missense Mutation (SNP) | VAF 88/323 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- MARCHF7 | c.1109C>T p.S370L | Missense Mutation (SNP) | VAF 102/297 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MAST4 | c.6949G>A p.D2317N (on ENST00000403625 / NM_001164664.2; = p.D2128N on NM_015183.3) | Missense Mutation (SNP) | VAF 110/379 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- MDN1 | c.1523G>A p.G508E | Missense Mutation (SNP) | VAF 113/478 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- MEP1A | c.1841A>C p.Q614P | Missense Mutation (SNP) | VAF 105/474 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- MEP1B | c.12G>A p.W4* | Nonsense Mutation (SNP) | VAF 118/325 reads (36%) | called by muse, mutect2, varscan2
- MMRN1 | c.2359C>T p.Q787* | Nonsense Mutation (SNP) | VAF 85/290 reads (29%) | called by muse, mutect2, varscan2
- MOB3A | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 147/399 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MPP4 | c.991dup p.L331Pfs*10 | Frame Shift Ins (INS) | VAF 74/297 reads (25%) | called by mutect2, pindel, varscan2
- MPV17 | c.316C>T p.P106S | Missense Mutation (SNP) | VAF 115/353 reads (33%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2, varscan2
- MTMR1 | c.214G>A p.G72S | Missense Mutation (SNP) | VAF 88/277 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0.045); called by muse, varscan2
- MUC16 | c.17255C>T p.T5752I | Missense Mutation (SNP) | VAF 79/272 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.352); called by muse, mutect2
- MUC21 | c.971C>T p.S324F | Missense Mutation (SNP) | VAF 169/822 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- MUC5B | c.11073G>A p.W3691* | Nonsense Mutation (SNP) | VAF 157/608 reads (26%) | called by muse, varscan2
- MUC5B | c.13490C>T p.P4497L | Missense Mutation (SNP) | VAF 192/650 reads (30%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- MVP | c.2036G>A p.R679K | Missense Mutation (SNP) | VAF 69/256 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- MXRA5 | c.1672C>T p.Q558* | Nonsense Mutation (SNP) | VAF 137/406 reads (34%) | called by muse, mutect2, varscan2
- MYH7B | c.5482G>A p.E1828K | Missense Mutation (SNP) | VAF 257/493 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MYO15A | c.2549C>T p.P850L | Missense Mutation (SNP) | VAF 133/436 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- MYO18B | c.1567G>A p.G523R | Missense Mutation (SNP) | VAF 91/399 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- MYO1E | c.1281A>T p.E427D | Missense Mutation (SNP) | VAF 37/155 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MYO3B | c.1948G>A p.E650K | Missense Mutation (SNP) | VAF 21/354 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); called by muse, mutect2
- MYT1 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 398/892 reads (45%) | SIFT tolerated (0.53); PolyPhen benign (0.011); called by muse, varscan2
- NALCN | c.4557G>A p.M1519I | Missense Mutation (SNP) | VAF 90/323 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- NCOA2 | c.1451C>T p.S484F | Missense Mutation (SNP) | VAF 136/436 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- NEB | c.6108A>T p.K2036N | Missense Mutation (SNP) | VAF 89/296 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- NKX2-2 | c.529C>T p.Q177* | Nonsense Mutation (SNP) | VAF 127/551 reads (23%) | called by muse, mutect2, varscan2
- NLRP13 | c.1318G>A p.V440M | Missense Mutation (SNP) | VAF 142/388 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- NONO | c.550C>T p.R184* | Nonsense Mutation (SNP) | VAF 113/392 reads (29%) | called by muse, mutect2, varscan2
- NONO | c.1276G>T p.G426* | Nonsense Mutation (SNP) | VAF 92/293 reads (31%) | called by muse, mutect2, varscan2
- NOS1 | c.1963G>A p.D655N | Missense Mutation (SNP) | VAF 69/215 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NPAS2 | c.1253C>T p.S418F | Missense Mutation (SNP) | VAF 73/268 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NPIPB11 | c.2924C>T p.P975L | Missense Mutation (SNP) | VAF 98/543 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- NR4A3 | c.952-1G>A p.X318_splice | Splice Site (SNP) | VAF 60/165 reads (36%) | called by muse, mutect2, varscan2
- NRAP | c.2808G>A p.M936I (on ENST00000359988 / NM_001322945.2; = p.M901I on NM_006175.4) | Missense Mutation (SNP) | VAF 98/297 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NRP1 | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 135/404 reads (33%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- NSD1 | c.6061C>T p.H2021Y | Missense Mutation (SNP) | VAF 87/229 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NSD2 | c.1882-1G>A p.X628_splice | Splice Site (SNP) | VAF 10/231 reads (4%) | called by muse, mutect2
- OAZ3 | c.466G>A p.G156S | Missense Mutation (SNP) | VAF 62/302 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- OMD | c.497G>A p.R166K | Missense Mutation (SNP) | VAF 97/352 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- OR10G9 | c.160C>T p.H54Y | Missense Mutation (SNP) | VAF 95/385 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- OR13C8 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 74/311 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR1J4 | c.791C>T p.S264F | Missense Mutation (SNP) | VAF 73/371 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- OR52I2 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 103/352 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR8B4 | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 99/330 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- OR9H1P | c.710C>T p.S237F | Missense Mutation (SNP) | VAF 74/332 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- OTOGL | c.2938G>A p.D980N (on ENST00000547103; = p.D971N on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/199 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PADI4 | c.1160C>T p.P387L | Missense Mutation (SNP) | VAF 59/221 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, varscan2
- PALB2 | c.2102C>T p.S701F | Missense Mutation (SNP) | VAF 140/421 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- PAM | c.1328G>A p.G443D | Missense Mutation (SNP) | VAF 107/375 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- PANK2 | c.142C>T p.L48F | Missense Mutation (SNP) | VAF 152/559 reads (27%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PAPPA | c.1764G>A p.M588I | Missense Mutation (SNP) | VAF 101/329 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- PARD3B | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 131/395 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PCDH18 | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 85/301 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- PCED1B | c.1153C>T p.P385S | Missense Mutation (SNP) | VAF 142/418 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- PCLO | c.12556C>T p.Q4186* | Nonsense Mutation (SNP) | VAF 207/554 reads (37%) | called by muse, mutect2, varscan2
- PCLO | c.8645G>A p.G2882E | Missense Mutation (SNP) | VAF 110/528 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); called by muse, varscan2
- PCOLCE2 | c.532G>A p.G178R | Missense Mutation (SNP) | VAF 103/306 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PCSK5 | c.1138G>A p.D380N | Missense Mutation (SNP) | VAF 90/271 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PCYOX1 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 97/365 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- PDE2A | c.634G>A p.G212R | Missense Mutation (SNP) | VAF 150/486 reads (31%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDE8B | c.649G>C p.V217L | Missense Mutation (SNP) | VAF 29/253 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PHF8 | c.1684G>A p.D562N (on ENST00000357988 / NM_001184896.1; = p.D526N on NM_015107.3) | Missense Mutation (SNP) | VAF 157/484 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- PHLDB3 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 153/506 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIEZO2 | c.6544G>A p.E2182K | Missense Mutation (SNP) | VAF 111/317 reads (35%) | SIFT tolerated (0.5); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PKD1L3 | c.3467T>A p.V1156D | Missense Mutation (SNP) | VAF 110/342 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- PLA2G4F | c.1580G>A p.G527E | Missense Mutation (SNP) | VAF 115/366 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PLCH1 | c.1976C>T p.A659V (on ENST00000340059 / NM_001130960.2; = p.A671V on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 114/329 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- PLCL1 | c.896C>T p.T299I | Missense Mutation (SNP) | VAF 93/289 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- PLCL2 | c.3234G>C p.K1078N (on ENST00000615277 / NM_001144382.2; = p.K952N on NM_015184.5) | Missense Mutation (SNP) | VAF 76/268 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- PLXNA3 | c.4843G>C p.A1615P | Missense Mutation (SNP) | VAF 116/391 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PLXNB3 | c.3442C>T p.P1148S | Missense Mutation (SNP) | VAF 212/584 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PMPCB | c.1089G>A p.W363* | Nonsense Mutation (SNP) | VAF 68/404 reads (17%) | called by muse, mutect2, varscan2
- POLL | c.450T>G p.D150E | Missense Mutation (SNP) | VAF 46/331 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, varscan2
- POP1 | c.1990C>T p.P664S | Missense Mutation (SNP) | VAF 121/342 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- POTEA | c.2008G>A p.E670K (on ENST00000519951 / NM_001005365.2; = p.E624K on NM_001002920.1) | Missense Mutation (SNP) | VAF 85/240 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- POTEE | c.1728A>C p.R576S | Missense Mutation (SNP) | VAF 69/262 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PPM1L | c.731G>A p.R244K | Missense Mutation (SNP) | VAF 58/184 reads (32%) | SIFT tolerated (0.96); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRDM4 | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 102/294 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PRR14 | c.755C>T p.S252F | Missense Mutation (SNP) | VAF 114/393 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRR5L | c.1097C>T p.S366F | Missense Mutation (SNP) | VAF 11/274 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- PRSS41 | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 62/256 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- PTER | c.496A>T p.I166F | Missense Mutation (SNP) | VAF 100/308 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.006); called by mutect2, varscan2
- PTPRF | c.1927T>C p.S643P | Missense Mutation (SNP) | VAF 149/492 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- PTPRQ | c.6352G>A p.D2118N (on ENST00000616559; = p.D2085N on NM_001145026.2) | Missense Mutation (SNP) | VAF 97/322 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PYROXD2 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 108/338 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RALGDS | c.1693C>T p.P565S | Missense Mutation (SNP) | VAF 85/245 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBMXL3 | c.329G>A p.R110K | Missense Mutation (SNP) | VAF 150/527 reads (28%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RFX4 | c.45G>A p.E15= | Splice Region (SNP) | VAF 57/171 reads (33%) | called by muse, mutect2, varscan2
- RGP1 | c.782C>T p.T261I | Missense Mutation (SNP) | VAF 85/248 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- RGS13 | c.131G>A p.G44D | Missense Mutation (SNP) | VAF 107/247 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RGS9 | c.221G>A p.G74D | Missense Mutation (SNP) | VAF 63/214 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNASE11 | c.265A>C p.N89H | Missense Mutation (SNP) | VAF 82/274 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.094); called by muse, mutect2
- ROBO2 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 73/285 reads (26%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- RORB | c.994G>A p.E332K (on ENST00000396204 / NM_001365023.1; = p.E321K on NM_006914.4) | Missense Mutation (SNP) | VAF 68/246 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- RXFP1 | c.972G>A p.L324= | Splice Region (SNP) | VAF 36/161 reads (22%) | called by muse, mutect2, varscan2
- SACS | c.11170C>T p.L3724F | Missense Mutation (SNP) | VAF 114/395 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- SCAF11 | c.821C>T p.T274I | Missense Mutation (SNP) | VAF 50/191 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SCN1A | c.3027G>A p.M1009I (on ENST00000303395 / NM_001202435.3; = p.M998I on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/241 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- SCRT2 | c.409G>A p.G137S | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- SDK1 | c.3623C>T p.S1208F | Missense Mutation (SNP) | VAF 93/492 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- SEMA4A | c.730T>G p.Y244D | Missense Mutation (SNP) | VAF 72/326 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- SEMA5A | c.1799C>T p.P600L | Missense Mutation (SNP) | VAF 171/346 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- SERPING1 | c.634G>A p.G212S | Missense Mutation (SNP) | VAF 114/412 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SETBP1 | c.1853C>T p.P618L | Missense Mutation (SNP) | VAF 105/342 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- SHOX | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 14/418 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- SLC10A2 | c.943C>T p.H315Y | Missense Mutation (SNP) | VAF 54/204 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC15A1 | c.1915G>A p.A639T | Missense Mutation (SNP) | VAF 90/280 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- SLC17A2 | c.1153G>A p.G385R | Missense Mutation (SNP) | VAF 97/408 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- SLC22A6 | c.886G>A p.G296R | Missense Mutation (SNP) | VAF 14/321 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.975); called by muse, mutect2
- SLC35C2 | c.583C>T p.Q195* | Nonsense Mutation (SNP) | VAF 13/448 reads (3%) | called by muse, mutect2
- SLC35F6 | c.179C>T p.S60F | Missense Mutation (SNP) | VAF 81/300 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.569); called by muse, mutect2, varscan2
- SLC4A10 | c.745C>A p.P249T | Missense Mutation (SNP) | VAF 71/274 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- SLC4A8 | c.1144C>T p.L382F | Missense Mutation (SNP) | VAF 23/390 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- SLC5A1 | c.999G>A p.M333I | Missense Mutation (SNP) | VAF 66/342 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC5A8 | c.856G>A p.G286R | Missense Mutation (SNP) | VAF 12/346 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- SLC6A2 | c.497C>T p.S166F | Missense Mutation (SNP) | VAF 20/404 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SLC9A2 | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 114/371 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- SMC1B | c.2152G>A p.E718K | Missense Mutation (SNP) | VAF 218/448 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- SMC6 | c.2219C>A p.T740N | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.16); called by mutect2, varscan2
- SMC6 | c.2218A>T p.T740S | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- SNRNP200 | c.4711C>T p.L1571F | Missense Mutation (SNP) | VAF 135/424 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- SNX25 | c.1928C>T p.S643F | Missense Mutation (SNP) | VAF 68/205 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- SOGA3 | c.2501C>T p.A834V | Missense Mutation (SNP) | VAF 285/567 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- SPAG17 | c.3488C>T p.P1163L | Missense Mutation (SNP) | VAF 126/331 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- SPATA31A7 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 114/732 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.326); called by muse, mutect2
- SPATA31E1 | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 63/400 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- SPEF2 | c.5376T>G p.F1792L | Missense Mutation (SNP) | VAF 84/187 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPON1 | c.917C>T p.S306F | Missense Mutation (SNP) | VAF 95/311 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- STAB2 | c.1563G>T p.M521I | Missense Mutation (SNP) | VAF 79/237 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- STARD3NL | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 94/622 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- STX19 | c.480G>T p.E160D | Missense Mutation (SNP) | VAF 99/317 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- STXBP5L | c.1117C>T p.Q373* | Nonsense Mutation (SNP) | VAF 95/230 reads (41%) | called by muse, mutect2, varscan2
- SUGP1 | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 128/400 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- SVEP1 | c.9593G>A p.S3198N | Missense Mutation (SNP) | VAF 125/363 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SYNE1 | c.249G>A p.M83I | Missense Mutation (SNP) | VAF 62/314 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.033); called by muse, varscan2
- SYNE3 | c.2114C>T p.S705F | Missense Mutation (SNP) | VAF 120/366 reads (33%) | SIFT tolerated (0.69); PolyPhen benign (0.232); called by muse, varscan2
- TAAR9 | c.922C>T p.P308S | Missense Mutation (SNP) | VAF 154/330 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TBX3 | c.1177G>C p.A393P (on ENST00000257566 / NM_016569.4; = p.A373P on NM_005996.4) | Missense Mutation (SNP) | VAF 112/372 reads (30%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- TCP11 | c.581G>A p.G194E (on ENST00000512012; = p.G132E on NM_018679.5) | Missense Mutation (SNP) | VAF 142/274 reads (52%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- TENM1 | c.2984C>T p.S995L | Missense Mutation (SNP) | VAF 104/370 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TENM4 | c.7865C>T p.P2622L | Missense Mutation (SNP) | VAF 133/400 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- TENM4 | c.6766G>A p.D2256N | Missense Mutation (SNP) | VAF 114/417 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TENT5D | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 166/529 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TEX11 | c.1653+1G>A p.X551_splice (on ENST00000344304; = p.X536_splice on NM_031276.3) | Splice Site (SNP) | VAF 77/244 reads (32%) | called by muse, mutect2, varscan2
- TFE3 | c.1040A>T p.K347M | Missense Mutation (SNP) | VAF 108/336 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- TFR2 | c.62C>T p.T21I | Missense Mutation (SNP) | VAF 88/546 reads (16%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TKTL2 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 98/298 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TLR8 | c.377A>C p.N126T (on ENST00000218032 / NM_138636.5; = p.N144T on NM_016610.4) | Missense Mutation (SNP) | VAF 141/409 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- TLR8 | c.2519C>T p.T840I (on ENST00000218032 / NM_138636.5; = p.T858I on NM_016610.4) | Missense Mutation (SNP) | VAF 19/469 reads (4%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2
- TM9SF4 | c.316C>T p.Q106* | Nonsense Mutation (SNP) | VAF 118/510 reads (23%) | called by muse, mutect2, varscan2
- TMEM132E | c.1733T>G p.V578G (on ENST00000321639; = p.V668G on NM_001304438.2) | Missense Mutation (SNP) | VAF 106/300 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- TMEM19 | c.503C>T p.S168F | Missense Mutation (SNP) | VAF 135/399 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- TMEM45A | c.307G>A p.G103R | Missense Mutation (SNP) | VAF 108/348 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- TMPRSS11B | c.45G>A p.W15* | Nonsense Mutation (SNP) | VAF 104/268 reads (39%) | called by muse, mutect2, varscan2
- TNNT1 | c.329G>A p.R110K | Missense Mutation (SNP) | VAF 68/300 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TNRC6C | c.1816C>T p.L606F | Missense Mutation (SNP) | VAF 87/262 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- TRAV34 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 105/331 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- TRBJ2-2 | c.3G>A p.*1= | Missense Mutation (SNP) | VAF 57/259 reads (22%) | called by muse, mutect2, varscan2
- TRHDE | c.2258C>T p.P753L | Missense Mutation (SNP) | VAF 117/352 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TRIM43B | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 82/323 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- TRIM49 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 50/188 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- TRIM55 | c.755C>T p.S252F | Missense Mutation (SNP) | VAF 120/350 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- TROAP | c.1645C>T p.P549S | Missense Mutation (SNP) | VAF 145/447 reads (32%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- TRPC5 | c.2686C>T p.Q896* | Nonsense Mutation (SNP) | VAF 165/445 reads (37%) | called by muse, mutect2, varscan2
- TRPM5 | c.3180G>C p.E1060D | Missense Mutation (SNP) | VAF 121/459 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- TSHR | c.2209G>A p.D737N | Missense Mutation (SNP) | VAF 115/347 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TSPOAP1 | c.218G>A p.G73E | Missense Mutation (SNP) | VAF 119/396 reads (30%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TTC39A | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 73/246 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- TTN | c.32761C>T p.P10921S (on ENST00000591111; = p.P9994S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 67/242 reads (28%) | PolyPhen benign (0.025); called by muse, mutect2, varscan2
- TUBB1 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 90/395 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- UBC | c.1126C>T p.R376C | Missense Mutation (SNP) | VAF 183/630 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- UFL1 | c.175C>A p.P59T | Missense Mutation (SNP) | VAF 82/382 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ULK2 | c.3001G>A p.G1001S | Missense Mutation (SNP) | VAF 109/335 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UNC13A | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 33/342 reads (10%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.07); called by muse, mutect2
- UNC5A | c.1915G>A p.E639K | Missense Mutation (SNP) | VAF 116/226 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- USP32 | c.761C>T p.S254F | Missense Mutation (SNP) | VAF 90/277 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- UVRAG | c.1124C>T p.S375F | Missense Mutation (SNP) | VAF 100/305 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- VCX | c.230G>A p.S77N | Missense Mutation (SNP) | VAF 59/300 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- VIL1 | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 109/380 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- VPS35 | c.2251C>T p.R751* | Nonsense Mutation (SNP) | VAF 72/240 reads (30%) | called by muse, mutect2, varscan2
- WDR76 | c.1069C>T p.H357Y | Missense Mutation (SNP) | VAF 107/294 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- YTHDC2 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 27/352 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- ZBTB20 | c.427C>T p.P143S (on ENST00000474710 / NM_001164342.2; = p.P70S on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 123/394 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZFHX3 | c.1955C>T p.S652F | Missense Mutation (SNP) | VAF 152/413 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
424 further variants in this file (13 protein-altering or splice-affecting, 362 silent, 49 other) are not listed here.
